Somatic mutation profile of tumor specimen ALCH-AD3G-TTP1-A (aliquot ALCH-AD3G-TTP1-A-1-0-D-A502-36) from ALCHEMIST case ALCH-AD3G, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 78.7 years (28,741 days).
Specimen ALCH-AD3G-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 337b46e7-9fe1-4aeb-b97f-31f47fef7037.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AD3G-NB1-A (Blood Derived Normal), aliquot ALCH-AD3G-NB1-A-1-0-D-A502-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e667d531-1cef-43c9-95e2-b07b7946a165

The open-access MAF lists 48 somatic variants for this specimen: 35 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 10, 5'UTR 2, Intron 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 185/914 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.395A>G p.K132R | Missense Mutation (SNP) | VAF 70/342 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1057519996, COSV52666637, COSV52701687, COSV52759171; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ARHGEF28 | c.3106G>C p.D1036H | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV55247202; called by muse, mutect2
- CADM2 | c.1022C>A p.T341K (on ENST00000407528 / NM_001167674.2; = p.T343K on NM_153184.4) | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as COSV67409440; called by muse, mutect2
- DNAH14 | c.5204G>A p.R1735K (on ENST00000445597; = p.R2140K on NM_001367479.1) | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1558099602; called by muse, mutect2, varscan2
- ENGASE | c.1796G>A p.C599Y | Missense Mutation (SNP) | VAF 43/251 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs1402826347; called by muse, mutect2, varscan2
- GLIS3 | c.503C>G p.S168W | Missense Mutation (SNP) | VAF 50/458 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60927317; called by muse, mutect2, varscan2
- GPR162 | c.1102C>T p.R368C (on ENST00000311268 / NM_019858.2; = p.R84C on NM_014449.2) | Missense Mutation (SNP) | VAF 62/276 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs146164363; called by muse, mutect2, varscan2
- HOXB7 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 12/268 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as rs1567978865; called by muse, mutect2
- KLKB1 | c.1340T>C p.I447T | Missense Mutation (SNP) | VAF 145/527 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1199356136; called by muse, mutect2, varscan2
- NCAM1 | c.1189G>A p.A397T (on ENST00000316851 / NM_181351.5; = p.A387T on NM_000615.7) | Missense Mutation (SNP) | VAF 26/312 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs781876684, COSV57518403; called by muse, mutect2
- NLGN1 | c.2393A>G p.N798S | Missense Mutation (SNP) | VAF 46/209 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.156); catalogued as rs765953828; called by muse, mutect2, varscan2
- PLPPR4 | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 41/240 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV64570652; called by muse, mutect2, varscan2
- POLI | c.2045C>T p.A682V | Missense Mutation (SNP) | VAF 41/198 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs1361058913; called by muse, mutect2, varscan2
- SLC5A2 | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1032587663, COSV57891982; called by muse, mutect2, varscan2
- SMC1A | c.1627G>C p.D543H | Missense Mutation (SNP) | VAF 115/581 reads (20%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.939); catalogued as CM166996; called by muse, mutect2, varscan2
- TBX4 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 212/773 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762743351; called by muse, mutect2, varscan2
- TTC22 | c.1397C>T p.S466F | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as rs1465737407, COSV64881815; called by muse, mutect2, varscan2
- ALX1 | c.487G>C p.E163Q | Missense Mutation (SNP) | VAF 25/235 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- FAHD2B | c.795-4C>T | Splice Region (SNP) | VAF 11/199 reads (6%) | called by muse, mutect2
- FREM2 | c.8532C>G p.I2844M | Missense Mutation (SNP) | VAF 56/420 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FSIP2 | c.7420G>T p.E2474* | Nonsense Mutation (SNP) | VAF 7/96 reads (7%) | called by muse, mutect2
- GFPT2 | c.1519A>G p.I507V | Missense Mutation (SNP) | VAF 20/466 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.472); called by muse, mutect2
- KCNJ5 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 30/521 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MIER1 | c.1213G>C p.V405L (on ENST00000355356 / NM_001077701.3; = p.V422L on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2
- PCDHGB4 | c.499C>G p.L167V | Missense Mutation (SNP) | VAF 48/407 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- PTPRM | c.3511T>A p.Y1171N | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SLC22A3 | c.1546C>G p.L516V | Missense Mutation (SNP) | VAF 138/735 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- SLC44A5 | c.6T>A p.N2K | Missense Mutation (SNP) | VAF 10/245 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SLC6A8 | c.970C>T p.L324F | Missense Mutation (SNP) | VAF 19/601 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ST6GAL2 | c.1397G>A p.C466Y | Missense Mutation (SNP) | VAF 42/216 reads (19%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UTP15 | c.577G>C p.D193H | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- WIPI2 | c.31G>A p.G11S | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF711 | c.11G>A p.G4D | Missense Mutation (SNP) | VAF 12/338 reads (4%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.003); called by muse, mutect2
- ZNHIT2 | c.5A>G p.E2G | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- CARNS1 | c.1938C>T p.T646= | Silent (SNP) | VAF 23/163 reads (14%) | catalogued as rs769514489; called by muse, mutect2, varscan2
- GIGYF2 | c.1260C>G p.A420= | Silent (SNP) | VAF 38/397 reads (10%) | catalogued as rs1420200889; called by muse, mutect2
- PLA2G4F | c.1926C>T p.L642= | Silent (SNP) | VAF 51/467 reads (11%) | called by muse, mutect2
- PSG6 | c.54C>A p.L18= | Silent (SNP) | VAF 41/318 reads (13%) | catalogued as rs770622700; called by muse, mutect2, varscan2
- RBMXL2 | c.999C>T p.S333= | Silent (SNP) | VAF 12/119 reads (10%) | catalogued as rs1565036300; called by muse, mutect2, varscan2
- TLL2 | c.960T>C p.D320= | Silent (SNP) | VAF 28/192 reads (15%) | catalogued as rs527907168; called by muse, mutect2, varscan2
- TRIM47 | c.558A>G p.L186= | Silent (SNP) | VAF 10/124 reads (8%) | called by muse, mutect2
- TRIP11 | c.3690C>T p.T1230= | Silent (SNP) | VAF 20/248 reads (8%) | catalogued as COSV99970413; called by muse, mutect2
- ZC3H12B | c.1870C>A p.R624= | Silent (SNP) | VAF 42/459 reads (9%) | called by muse, mutect2
- ZNF574 | c.1785C>T p.L595= | Silent (SNP) | VAF 26/194 reads (13%) | called by muse, mutect2, varscan2
- CCDC171 | c.-21T>G | 5'UTR (SNP) | VAF 12/85 reads (14%) | called by muse, mutect2, varscan2
- FUS | c.-34C>T | 5'UTR (SNP) | VAF 25/403 reads (6%) | catalogued as rs765945796, COSV99568529, COSV99569043; called by muse, mutect2
- MICOS10 | c.64+11417A>G | Intron (SNP) | VAF 18/214 reads (8%) | called by muse, mutect2
